Somatic mutation profile of tumor specimen b2615b47-5ac2-4775-9205-50990d (aliquot b2615b47-5ac2-4775-9205-50990d_D6_1) from CPTAC case 05CO026, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB.
Specimen b2615b47-5ac2-4775-9205-50990d: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 25929b24-3cd2-4b78-b770-527f6a7c9b35.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen a9f7cc96-dfaa-4b22-99a7-037ead (Blood Derived Normal), aliquot a9f7cc96-dfaa-4b22-99a7-037ead_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e4612591-6513-4808-b88a-7d21cebf3357

The open-access MAF lists 149 somatic variants for this specimen: 103 protein-altering or splice-affecting, 31 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 88, Silent 31, Nonsense Mutation 9, Intron 7, Frame Shift Del 5, RNA 5, 3'UTR 2, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 66/211 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- OTOGL | c.5014C>T p.R1672* (on ENST00000547103; = p.R1663* on NM_173591.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 27/140 reads (19%) | catalogued as rs759174628, COSV54015901; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PGAP2 | c.46C>T p.R16W | Missense Mutation (SNP) | VAF 51/139 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773359554, CM132498, COSV53466228; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABLIM3 | c.1178G>A p.R393H | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.046); catalogued as rs753998757, COSV58639677, COSV58650142; called by muse, mutect2, varscan2
- ALX4 | c.646C>T p.R216W | Missense Mutation (SNP) | VAF 126/397 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587777700, CM147007, COSV61324811; called by muse, mutect2, varscan2
- ANO7 | c.1138C>G p.P380A (on ENST00000274979; = p.P326A on NM_001370694.2) | Missense Mutation (SNP) | VAF 41/162 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.46); catalogued as rs765063722; called by muse, mutect2, varscan2
- APC | c.4128del p.Y1376* | Frame Shift Del (DEL) | VAF 158/421 reads (38%) | catalogued as CD058149, CM106639, COSV57326134, COSV57340615, COSV57378080; called by mutect2, pindel, varscan2
- ARHGAP22 | c.1618C>T p.R540C | Missense Mutation (SNP) | VAF 27/133 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs866971467, COSV50950759; called by muse, mutect2, varscan2
- ATP11B | c.1726C>T p.R576C | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60027356; called by muse, mutect2, varscan2
- C10orf71 | c.3814G>A p.A1272T | Missense Mutation (SNP) | VAF 58/241 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.04); catalogued as rs1472853354, COSV60505092; called by muse, mutect2, varscan2
- CCDC185 | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 65/232 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs749086241, COSV100838805; called by muse, mutect2, varscan2
- CRYZ | c.898G>C p.G300R | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.193); catalogued as rs374694701, COSV100558668, COSV61718681; called by muse, mutect2, varscan2
- DCP1B | c.1580C>T p.P527L | Missense Mutation (SNP) | VAF 92/552 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54972380; called by muse, mutect2, varscan2
- DNAH10 | c.1523C>T p.S508L (on ENST00000409039; = p.S447L on NM_207437.3) | Missense Mutation (SNP) | VAF 46/241 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.134); catalogued as rs145065895; called by muse, mutect2, varscan2
- ECEL1 | c.499C>T p.R167W | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs1275600002; called by muse, mutect2, varscan2
- EIF4G1 | c.4438C>T p.R1480* (on ENST00000346169 / NM_198241.3; = p.R1285* on NM_004953.5) | Nonsense Mutation (SNP) | VAF 152/709 reads (21%) | catalogued as COSV59990065; called by muse, mutect2, varscan2
- EPHA6 | c.2805G>T p.R935S | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV67590471; called by muse, mutect2, varscan2
- FAM166A | c.517C>T p.H173Y | Missense Mutation (SNP) | VAF 40/142 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763493368; called by mutect2, varscan2
- FMO5 | c.191C>A p.S64Y | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54208186; called by muse, mutect2, varscan2
- GOLGA6L2 | c.866G>A p.R289Q | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.106); catalogued as rs781198730; called by muse, mutect2, varscan2
- GPATCH1 | c.150C>G p.H50Q | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99404374; called by muse, mutect2, varscan2
- GPR61 | c.109C>T p.R37W | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as rs777705427, COSV68178375; called by muse, mutect2, varscan2
- GTDC1 | c.1282C>T p.H428Y (on ENST00000344850 / NM_001354361.1; = p.H343Y on NM_024659.6 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs367849783; called by mutect2, varscan2
- HDAC6 | c.828C>A p.H276Q | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61928616; called by muse, varscan2
- JAK2 | c.1687G>A p.V563I | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.82); PolyPhen benign (0.003); catalogued as rs895187915, COSV67638292; called by muse, mutect2, varscan2
- JARID2 | c.899G>A p.R300Q | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.382); catalogued as rs1360210107; called by muse, mutect2, varscan2
- KMT2C | c.12466A>G p.R4156G | Missense Mutation (SNP) | VAF 94/248 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV51435650; called by muse, mutect2, varscan2
- LRRC4C | c.466C>T p.R156* | Nonsense Mutation (SNP) | VAF 54/219 reads (25%) | catalogued as COSV53426135; called by muse, mutect2, varscan2
- MAGEL2 | c.3256G>A p.A1086T | Missense Mutation (SNP) | VAF 100/336 reads (30%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.001); catalogued as rs753866114, COSV100046042, COSV58568359; called by muse, mutect2, varscan2
- MN1 | c.3778G>T p.E1260* | Nonsense Mutation (SNP) | VAF 20/54 reads (37%) | catalogued as COSV56562574; called by muse, varscan2
- N4BP1 | c.1330_1331del p.Q444Vfs*8 | Frame Shift Del (DEL) | VAF 36/143 reads (25%) | catalogued as rs777170154; called by mutect2, pindel, varscan2
- NALCN | c.170C>T p.T57M | Missense Mutation (SNP) | VAF 63/139 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1188144130, COSV51918402, COSV99216118; called by muse, mutect2, varscan2
- NPFFR2 | c.106G>A p.V36I | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs757021469, COSV58148438, COSV58154206; called by muse, mutect2, varscan2
- NYAP2 | c.1703C>T p.A568V | Missense Mutation (SNP) | VAF 73/358 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs1361526299, COSV56007357; called by muse, mutect2, varscan2
- OR13C2 | c.829G>A p.D277N | Missense Mutation (SNP) | VAF 52/171 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.172); catalogued as rs770272284, COSV73377772; called by muse, mutect2, varscan2
- OR1A1 | c.221C>T p.S74L | Missense Mutation (SNP) | VAF 85/396 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.424); catalogued as rs267604805, COSV100410830, COSV58403914; called by muse, mutect2, varscan2
- OR2L8 | c.469G>T p.A157S | Missense Mutation (SNP) | VAF 82/418 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.672); catalogued as COSV99057419; called by muse, mutect2, varscan2
- PCDHGA2 | c.1778C>T p.A593V | Missense Mutation (SNP) | VAF 148/728 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.944); catalogued as COSV53947281; called by muse, mutect2, varscan2
- PDE2A | c.2600C>A p.A867E | Missense Mutation (SNP) | VAF 90/260 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); catalogued as COSV57807683; called by muse, mutect2, varscan2
- PDLIM7 | c.1003G>A p.V335M | Missense Mutation (SNP) | VAF 37/165 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.052); catalogued as rs761560775; called by muse, mutect2, varscan2
- PLPPR4 | c.1531G>A p.G511R | Missense Mutation (SNP) | VAF 16/268 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.067); catalogued as COSV64565087, COSV64566351; called by muse, mutect2
- PLXNA4 | c.5308T>C p.C1770R | Missense Mutation (SNP) | VAF 50/196 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58118472; called by muse, mutect2, varscan2
- PRMT9 | c.1076G>A p.R359Q | Missense Mutation (SNP) | VAF 54/170 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as rs763286581, COSV59359042; called by muse, mutect2, varscan2
- PRPF8 | c.5495G>T p.R1832L | Missense Mutation (SNP) | VAF 95/444 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59264706; called by muse, mutect2, varscan2
- PRR32 | c.592G>A p.G198R | Missense Mutation (SNP) | VAF 195/520 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs375664901, COSV64420309; called by muse, mutect2, varscan2
- PRRG1 | c.20C>T p.T7M | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.634); catalogued as rs782396046, COSV99059781; called by muse, mutect2, varscan2
- SAG | c.271C>T p.R91W | Missense Mutation (SNP) | VAF 50/185 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.861); catalogued as rs779840799; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SDCBP | c.314G>A p.R105K | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.311); catalogued as COSV52705824; called by muse, mutect2, varscan2
- SLC27A1 | c.941G>T p.R314L | Missense Mutation (SNP) | VAF 78/354 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as rs751148243; called by muse, mutect2, varscan2
- SLC39A4 | c.1635C>A p.F545L (on ENST00000301305 / NM_001374839.1; = p.F520L on NM_017767.3) | Missense Mutation (SNP) | VAF 104/333 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.673); catalogued as COSV52778926; called by mutect2, varscan2
- TRH | c.574G>A p.A192T | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.895); catalogued as COSV57014423; called by muse, mutect2, varscan2
- TRPS1 | c.758G>A p.R253H (on ENST00000220888 / NM_001330599.2; = p.R266H on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 79/273 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1410987986, COSV55252462; called by muse, mutect2, varscan2
- TRPV1 | c.1736G>A p.R579H | Missense Mutation (SNP) | VAF 103/220 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.406); catalogued as rs375321968; called by muse, mutect2, varscan2
- UCP2 | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 33/122 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs143754624; called by muse, mutect2, varscan2
- UNC13C | c.1173A>T p.L391F | Missense Mutation (SNP) | VAF 40/154 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs370327961; called by muse, mutect2, varscan2
- USH2A | c.1877G>A p.R626Q | Missense Mutation (SNP) | VAF 70/330 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs192524347, CM1310708, COSV56363484; ClinVar: uncertain significance; called by mutect2, varscan2
- ZBP1 | c.573G>T p.Q191H | Missense Mutation (SNP) | VAF 64/483 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59064289; called by muse, mutect2, varscan2
- ZNF732 | c.599G>A p.C200Y | Missense Mutation (SNP) | VAF 56/191 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs61730554; called by muse, mutect2, varscan2
- ADAMTS3 | c.3141_3142del p.C1047* | Nonsense Mutation (DEL) | VAF 30/136 reads (22%) | called by pindel, varscan2
- AKAP11 | c.5275A>T p.N1759Y | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- AP3B2 | c.2000G>A p.R667Q | Missense Mutation (SNP) | VAF 74/218 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- APBA2 | c.1999C>G p.L667V | Missense Mutation (SNP) | VAF 28/566 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.006); called by muse, mutect2
- ASCC3 | c.5582G>A p.R1861K | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- CACUL1 | c.693G>T p.M231I | Missense Mutation (SNP) | VAF 4/57 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); called by muse, mutect2
- CAMK2B | c.454G>T p.A152S | Missense Mutation (SNP) | VAF 95/338 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CC2D2A | c.3787G>A p.D1263N | Missense Mutation (SNP) | VAF 33/153 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CCL25 | c.377C>T p.S126L | Missense Mutation (SNP) | VAF 65/156 reads (42%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDH8 | c.2235G>T p.Q745H | Missense Mutation (SNP) | VAF 116/221 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); called by muse, varscan2
- CDK18 | c.232C>T p.Q78* | Nonsense Mutation (SNP) | VAF 56/269 reads (21%) | called by muse, mutect2, varscan2
- CFAP221 | c.2438C>A p.P813Q | Missense Mutation (SNP) | VAF 72/135 reads (53%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- COL3A1 | c.3599T>G p.V1200G | Missense Mutation (SNP) | VAF 61/268 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- CPEB3 | c.923G>A p.R308H | Missense Mutation (SNP) | VAF 63/228 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CPXCR1 | c.767T>A p.I256K | Missense Mutation (SNP) | VAF 35/227 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- EML6 | c.461T>A p.F154Y | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- EYA1 | c.991G>C p.E331Q | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- FAM171B | c.1798G>A p.A600T | Missense Mutation (SNP) | VAF 77/292 reads (26%) | SIFT tolerated (0.6); PolyPhen benign (0.012); called by mutect2, varscan2
- FAM217B | c.400G>A p.G134S | Missense Mutation (SNP) | VAF 111/427 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- FMNL2 | c.2798A>T p.N933I | Missense Mutation (SNP) | VAF 71/155 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- IGLON5 | c.841G>A p.V281M | Missense Mutation (SNP) | VAF 46/162 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); called by muse, varscan2
- KIAA1614 | c.1447G>A p.A483T | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- KIR2DL1 | c.319del p.S107Pfs*15 | Frame Shift Del (DEL) | VAF 100/251 reads (40%) | called by mutect2, varscan2*
- KIR2DL1 | c.324del p.Y109Ifs*13 | Frame Shift Del (DEL) | VAF 63/278 reads (23%) | called by mutect2*, pindel
- KMT2A | c.1736C>T p.S579F | Missense Mutation (SNP) | VAF 70/250 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- MAGEC1 | c.412T>A p.S138T | Missense Mutation (SNP) | VAF 46/518 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.153); called by muse, mutect2
- MNX1 | c.725G>T p.R242L | Missense Mutation (SNP) | VAF 77/258 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NCAN | c.3005C>G p.A1002G | Missense Mutation (SNP) | VAF 33/175 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NISCH | c.1869G>T p.E623D | Missense Mutation (SNP) | VAF 89/200 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- NR3C1 | c.220C>A p.Q74K | Missense Mutation (SNP) | VAF 55/233 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- NUDCD2 | c.189+1G>T p.X63_splice | Splice Site (SNP) | VAF 26/64 reads (41%) | called by muse, mutect2, varscan2
- NUP210L | c.3677del p.L1226Qfs*14 | Frame Shift Del (DEL) | VAF 65/141 reads (46%) | called by mutect2, pindel, varscan2
- PCDH15 | c.530C>A p.T177K | Missense Mutation (SNP) | VAF 48/231 reads (21%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- PLPP5 | c.148G>A p.V50M | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- POLR2A | c.2243C>A p.A748D | Missense Mutation (SNP) | VAF 196/423 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PPP3CA | c.835C>T p.R279* | Nonsense Mutation (SNP) | VAF 21/60 reads (35%) | called by muse, mutect2, varscan2
- SAMHD1 | c.395T>G p.L132R | Missense Mutation (SNP) | VAF 94/531 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TIMP2 | c.500C>G p.S167C | Missense Mutation (SNP) | VAF 66/465 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- TLN1 | c.2326C>T p.Q776* | Nonsense Mutation (SNP) | VAF 119/440 reads (27%) | called by muse, mutect2, varscan2
- TMEM184C | c.845G>A p.W282* | Nonsense Mutation (SNP) | VAF 21/83 reads (25%) | called by muse, mutect2, varscan2
- TNFRSF10D | c.14G>A p.G5E | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- TTN | c.31961A>C p.E10654A (on ENST00000591111; = p.E9727A on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/144 reads (8%) | PolyPhen benign (0.022); called by muse, mutect2
- UXS1 | c.1226C>T p.P409L | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZMYND15 | c.192C>A p.N64K | Missense Mutation (SNP) | VAF 36/158 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ZNF613 | c.1520C>T p.T507I (on ENST00000293471 / NM_001031721.4; = p.T471I on NM_024840.4) | Missense Mutation (SNP) | VAF 110/244 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- APOB | c.4818C>T p.Y1606= | Silent (SNP) | VAF 94/339 reads (28%) | catalogued as rs564437453, CM146581, COSV51937288; called by muse, mutect2, varscan2
- ATG14 | c.1395C>T p.I465= | Silent (SNP) | VAF 26/83 reads (31%) | catalogued as rs766410608; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.4071A>G p.P1357= | Silent (SNP) | VAF 63/315 reads (20%) | catalogued as rs928419585; called by muse, mutect2, varscan2
- C19orf57 | c.546G>A p.A182= | Silent (SNP) | VAF 41/130 reads (32%) | catalogued as rs760177608, COSV100694688; called by muse, mutect2, varscan2
- DIO2 | c.699G>T p.V233= | Silent (SNP) | VAF 78/264 reads (30%) | called by muse, mutect2, varscan2
- DNAH5 | c.12630C>T p.Y4210= | Silent (SNP) | VAF 183/434 reads (42%) | catalogued as rs766099303; called by muse, mutect2, varscan2
- DOCK9 | c.5856C>T p.D1952= (on ENST00000376460 / NM_001366676.2; = p.D1953= on NM_015296.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 53/242 reads (22%) | catalogued as rs771712709; called by muse, mutect2, varscan2
- EPPK1 | c.153G>A p.S51= | Silent (SNP) | VAF 37/96 reads (39%) | catalogued as rs371819951; called by muse, mutect2, varscan2
- EXOSC10 | c.1578A>G p.E526= | Silent (SNP) | VAF 44/140 reads (31%) | called by muse, mutect2, varscan2
- FAM9A | c.405A>G p.R135= | Silent (SNP) | VAF 26/127 reads (20%) | called by muse, mutect2, varscan2
- GAB4 | c.660C>T p.H220= | Silent (SNP) | VAF 29/89 reads (33%) | catalogued as rs762662155; called by muse, mutect2, varscan2
- GRM1 | c.549C>T p.I183= | Silent (SNP) | VAF 146/695 reads (21%) | catalogued as rs149386064, COSV51359809; called by muse, mutect2, varscan2
- HOXD9 | c.42T>C p.S14= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as rs757230770; called by muse, varscan2
- HRNR | c.5208T>A p.G1736= | Silent (SNP) | VAF 132/1232 reads (11%) | catalogued as COSV64261399; called by mutect2, varscan2
- KIF26B | c.5139C>T p.S1713= | Silent (SNP) | VAF 83/128 reads (65%) | called by muse, mutect2, varscan2
- KRT15 | c.1053C>T p.A351= | Silent (SNP) | VAF 63/390 reads (16%) | catalogued as rs746929205, COSV54178728; called by muse, mutect2, varscan2
- LATS2 | c.759C>T p.Y253= | Silent (SNP) | VAF 69/152 reads (45%) | catalogued as rs561201579; called by muse, mutect2, varscan2
- LCE1F | c.303G>A p.A101= | Silent (SNP) | VAF 56/130 reads (43%) | catalogued as rs748689613; called by muse, varscan2
- NFATC2 | c.942G>A p.S314= | Silent (SNP) | VAF 47/327 reads (14%) | catalogued as COSV101044960; called by muse, mutect2, varscan2
- NKAIN2 | c.417T>C p.C139= | Silent (SNP) | VAF 61/264 reads (23%) | called by muse, mutect2, varscan2
- NPAS4 | c.360C>T p.Y120= | Silent (SNP) | VAF 73/212 reads (34%) | catalogued as rs377576767, COSV60650442; called by muse, mutect2, varscan2
- OR11H1 | c.129A>T p.I43= | Silent (SNP) | VAF 51/532 reads (10%) | catalogued as rs1376219525; called by muse, mutect2, varscan2
- OR51Q1 | c.861G>A p.P287= | Silent (SNP) | VAF 47/153 reads (31%) | catalogued as rs759576333; called by muse, mutect2, varscan2
- PRICKLE3 | c.1317G>A p.P439= | Silent (SNP) | VAF 31/110 reads (28%) | catalogued as rs782649393; called by muse, mutect2, varscan2
- RIMS2 | c.576C>T p.P192= | Silent (SNP) | VAF 58/184 reads (32%) | called by muse, mutect2, varscan2
- SLC25A5 | c.267C>T p.F89= | Silent (SNP) | VAF 175/639 reads (27%) | catalogued as rs1379158202, COSV58626864; called by muse, mutect2, varscan2
- TNFAIP8L2 | c.300G>A p.T100= | Silent (SNP) | VAF 250/548 reads (46%) | catalogued as COSV64423606; called by muse, mutect2, varscan2
- WASHC2A | c.1431A>G p.Q477= | Silent (SNP) | VAF 18/84 reads (21%) | catalogued as rs1554885101; called by muse, mutect2, varscan2
- XYLT1 | c.2400G>A p.E800= | Silent (SNP) | VAF 91/322 reads (28%) | catalogued as rs777076989; called by muse, mutect2, varscan2
- ZBTB46 | c.906G>A p.T302= | Silent (SNP) | VAF 34/287 reads (12%) | catalogued as rs752342501; called by muse, mutect2, varscan2
- ZIC3 | c.348C>T p.R116= | Silent (SNP) | VAF 146/401 reads (36%) | called by muse, mutect2, varscan2
- ARHGAP42 | c.2457-1435C>G | Intron (SNP) | VAF 30/119 reads (25%) | called by muse, mutect2, varscan2
- C11orf96 | chr11:43943422 C>A | 3'Flank (SNP) | VAF 12/30 reads (40%) | catalogued as rs990619690; called by mutect2, varscan2
- C8orf31 | n.447C>T | RNA (SNP) | VAF 31/106 reads (29%) | catalogued as rs538935958; called by muse, mutect2, varscan2
- CCN5 | c.*140C>A | 3'UTR (SNP) | VAF 8/54 reads (15%) | called by muse, mutect2, varscan2
- DOCK2 | c.2800-48378C>T | Intron (SNP) | VAF 111/228 reads (49%) | catalogued as rs758134255, COSV56967939; called by mutect2, varscan2
- DUX4L4 | n.1051C>T | RNA (SNP) | VAF 17/150 reads (11%) | called by muse, mutect2, varscan2
- FAM90A20P | n.336G>A | RNA (SNP) | VAF 80/149 reads (54%) | catalogued as rs767403869; called by muse, mutect2, varscan2
- H2BC15 | c.377+2537G>T | Intron (SNP) | VAF 6/31 reads (19%) | called by muse, mutect2
- H3-2 | c.*89G>A | 3'UTR (SNP) | VAF 81/353 reads (23%) | catalogued as rs1553512958; called by muse, mutect2, varscan2
- MIR545 | n.22G>T | RNA (SNP) | VAF 74/234 reads (32%) | called by mutect2, varscan2
- PCDH11X | c.3033+3667A>G | Intron (SNP) | VAF 19/111 reads (17%) | called by muse, mutect2, varscan2
- PPM1F | c.355+1365T>A | Intron (SNP) | VAF 41/153 reads (27%) | called by muse, mutect2, varscan2
- SLC6A8 | c.778-64C>T | Intron (SNP) | VAF 185/478 reads (39%) | catalogued as rs782407281; called by muse, mutect2, varscan2
- SPATA31C1 | n.2688T>A | RNA (SNP) | VAF 125/432 reads (29%) | called by muse, mutect2, varscan2
- TTC29 | c.977+2035A>G | Intron (SNP) | VAF 19/78 reads (24%) | called by muse, mutect2, varscan2
